Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOB, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAOB-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATH []

Order Dr:

Order Clinic:

Order Dx:

Specimen Source: R TESTICLE SPER CORD

CASE NO.:

GROSS EXAM DATE:

PHYSICIAN & PAGER #:

--- CONCLUSION/DIAGNOSTIC CODE ---

NON-ROUTINE

--- REPORT ---

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. MIXED GERM CELL TUMOR UNIFOCAL (4 CM) COMPOSED OF TERATOMA (MATURE AND IMMATURE) 60%, EMBRYONAL CARCINOMA 30%, FOCI CONSISTENT WITH YOLK SAC TUMOR 5% AND CHORIOCARCINOMA (5%), right testicle and spermatic cord, right orchiectomy. (see note)
2. TUMOR CONFINED TO TESTIS.
3. NO LYMPHOVASCULAR INVASION IDENTIFIED.
4. INTRATUBULAR GERM CELL NEOPLASIA.
5. SURGICAL SPERMATIC CORD AND OTHER MARGINS FREE OF TUMOR.
6. TESTICULAR TISSUE WITH EVIDENCE OF SPERMATOGENESIS.
7. PT1NXMX.

Note: The embryonal carcinoma is strongly positive for CD30. There are small focal tubular areas of strong positivity for AFP and HCG.
notified on at

GROSS DESCRIPTION:

The specimen is received in one part, fixed in formalin, labeled with the patient's name, hospital number, and "right testis and spermatic cord." It consists of a 61-gram orchiectomy specimen including a 6 x 4.5 x 4-cm testis, a 1 x 1.2 x 0.5-cm epididymis, and 7 cm in length and 1.4 cm in diameter spermatic cord. The outer surface of the testis and spermatic cord are inked in black color At the base of the epididymis and 0.5 cm from the tunica albuginea there is a 4 x 3.5 x 3.5-cm white-tan variegated well-circumscribed mass with focal area of hemorrhage and necrosis. There is no gross involvement of the tunica albuginea or impingement on the epididymis. The rim of testicular

CKE ICD-O-3

Mixed embryonal carcinoma & teratoma 9081/3

path

Mixed germ cell tumor 9085/3

Site: @ Testis NOS C62.9

9/10/13/14

[page 2 of 3]
REPORT

parenchyma at the edge of the tumor is compressed and grossly unremarkable. The spermatic cord consists of vas deferens, arteries, and veins, and is unremarkable. Representative sections are submitted as follows: Cassettes 1 to 5 - Tumor. Cassette 6 - Tumor and base of epididymis. Cassette 7 - Tumor and tunica vaginalis. Cassette 8 - Tumor and adjacent testis. Cassette 9 - Spermatic cord resection margin. Cassette 10 - Spermatic cord midportion. Cassette 11 - Spermatic cord peritesticular portion. R11.

*Pw TSS dx discrepancy from
TCGA tumor is: embryonal 40%
mature teratoma 60%*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V1.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Teratoma (mature and immature) 60%, Embryonal Carcinoma 30%, Yolk Sac Tumor 5%, Choriocarcinoma 5%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Embryonal Carcinoma 40% Teratoma (mature) 60%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 0f2b03a7-3fe5-4b5d-a526-0feca0e873a3 (TCGA-XE-AAOB.39198F16-4D54-4793-97CD-36405D2815CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).